Gene-level copy-number profile of tumor specimen TCGA-EY-A1GJ-01A from TCGA case TCGA-EY-A1GJ, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 73.1 years (26,715 days).
Specimen TCGA-EY-A1GJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.9c296211-e36d-47dd-a48f-7a496ca47c97.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EY-A1GJ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/95e64a27-e127-4b25-b3ac-ad26ee851cc7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 12,386; copy number 2: 42,743; copy number 3: 3,202; copy number 4: 888; copy number 5: 243; copy number 6: 101; copy number 7: 26; copy number 8: 50; copy number 11: 29; copy number 14: 141.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EY-A1GJ-01A-12D-A141-01): tumor purity 0.92, ploidy 1.92, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:63,957,874–63,981,043, 2 genes: HTR1A, AC122707.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 590 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:15,834,474–16,352,480, 25 genes, copy number 6 (within-gene range 3–6): FLJ37453, SPEN, AL034555.1, ZBTB17, AL355994.4, AL355994.1, AL355994.5, TBC1D3P6, SRARP, AL355994.3, HSPB7, CLCNKA, AL355994.2, CLCNKB, FAM131C, EPHA2, AL451042.2, AL451042.1, ARHGEF19-AS1, ARHGEF19, ANO7L1, AL109627.1, CPLANE2, MT1XP1, FBXO42.
- chr1:22,266,239–23,379,029, 33 genes, copy number 5: MIR4418, PPIAP34, AL591122.1, ZBTB40, ZBTB40-IT1, EPHA8, MIR6127, C1QA, C1QC, C1QB, EPHB2, MIR4684, AL512444.1, MIR4253, LACTBL1, TEX46, KDM1A, AL031428.1, MIR3115, AL031428.2, LUZP1, AL161672.1, RNU6-514P, RNU6-135P, HTR1D, AL109936.1, LINC01355, AL109936.9, HNRNPR, ZNF436, ZNF436-AS1, Y_RNA, AL109936.2.
- chr1:30,711,277–30,860,254, 9 genes, copy number 5: MATN1, MATN1-AS1, AL137857.1, LAPTM5, MIR4420, AL137027.1, LINC01778, RN7SKP91, AL445235.1.
- chr8:123,768,439–123,815,452, 1 gene, copy number 6: FAM91A1.
- chr11:73,675,638–82,718,299, 183 genes, copy number 8–14 (within-gene range 1–14) (broad region; genes not listed).
- chr14:101,332,511–102,730,561, 36 genes, copy number 6: AL355096.1, LINC00524, LINC02314, AL049836.2, DIO3OS, MIR1247, DIO3, AL049836.1, LINC02320, AL355032.1, LINC00239, PPP2R5C, AL137779.2, RNU6-790P, AL137779.1, NPM1P20, AL118558.3, AL118558.4, DYNC1H1, AL118558.2, AL118558.1, RN7SL472P, HSP90AA1, WDR20, MOK, ZNF839, CINP, TECPR2, RNU6-244P, ANKRD9, MIR4309, LINC02323, RN7SL546P, RCOR1, RPL23AP11, Y_RNA.
- chr17:17,810,399–18,244,875, 17 genes, copy number 7 (within-gene range 2–7): SREBF1, MIR6777, MIR33B, TOM1L2, AC122129.1, DRC3, ATPAF2, BRI3P3, AC087163.1, AC087163.2, GID4, DRG2, AC087164.2, MYO15A, AC087164.1, ALKBH5, LLGL1.
- chr17:47,253,827–48,929,056, 87 genes, copy number 5–14 (within-gene range 3–14) (broad region; genes not listed).
- chr17:50,346,126–51,521,401, 53 genes, copy number 5–6: XYLT2, AC015909.5, MRPL27, EME1, LRRC59, Y_RNA, AC004707.1, ACSF2, MRPS21P9, CHAD, AC021491.4, RSAD1, AC021491.1, MYCBPAP, AC021491.2, EPN3, SPATA20, CACNA1G-AS1, CACNA1G, AC021491.3, AC004590.1, ABCC3, ANKRD40, AC005921.2, Y_RNA, LUC7L3, AC005921.3, ANKRD40CL, MIR8059, AC005921.4, AC005921.1, WFIKKN2, AC091062.1, RPL5P33, TOB1, TOB1-AS1, AC005920.4, AC005920.1, AC005920.3, SPAG9, AC005920.2, NME1, NME1-NME2, NME2, MBTD1, AC005839.1, AC006141.1, UTP18, LINC02071, AC005823.2, AC005823.1, LINC02073, RPL7P48.
- chr19:11,987,617–12,078,106, 2 genes, copy number 5 (within-gene range 3–5): ZNF433-AS1, AC008770.4.
- chr19:12,014,732–13,763,296, 106 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr20:31,274,170–31,723,989, 29 genes, copy number 11: DKKL1P1, AL121723.1, DEFB116, RPL31P3, HAUS6P2, RNA5SP480, DEFB117, DEFB118, AL031650.1, DEFB119, DEFB121, DEFB122, DEFB123, DEFB124, REM1, LINC00028, HM13, AL110115.1, MCTS2P, HM13-IT1, HM13-AS1, AL110115.2, RNU6-384P, ID1, MIR3193, COX4I2, BCL2L1, BCL2L1-AS1, ABALON.
- chr20:32,109,714–32,167,258, 1 gene, copy number 7 (within-gene range 3–7): TM9SF4.
- chr20:32,170,390–32,355,734, 8 genes, copy number 7: RSL24D1P6, TSPY26P, PLAGL2, POFUT1, MIR1825, AL121897.1, KIF3B, AL121583.1.

Autosomal genes at a single copy (total copy number 1): 12,381. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
